Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A197, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A197-06A (Metastatic).

PATIENT HISTORY:

No clinical history given.

PRE-OP DIAGNOSIS: Vulvar cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical vulvectomy, dissection groin, D&C, sentinel lymph node biopsy.

105-0-3

Melanoma, NOS

872013

12/14/10

FINAL DIAGNOSIS:

PART 1: ENDOCERVIX, "ECC", CURRETAGE-
A. FRAGMENTS OF SCANT MUCOID MATERIAL.
B. NO EVIDENCE OF MELANOMA.

PART 2: ENDOMETRIUM, "EMC", CURRETAGE-
A. ENDOMETRIUM WITH CYSTIC ATROPHY.
B. NO EVIDENCE OF MELANOMA.

PART 3: SOFT TISSUE, LEFT GROIN WITH SENTINEL NODE, DISSECTION-
METASTATIC MELANOMA IN ONE OUT OF TWELVE LYMPH NODES (1/12). FOCAL EXTRA CAPSULAR SPREAD
PRESENT.

PART 4: VULVAR, VULVECTOMY-
A. ULCERATED METASTATIC MELANOMA (8.0CM) IN SKIN AND SUBCUTANEOUS TISSUE (see comment).
B. MARGINS OF RESECTION ARE FREE OF TUMOR.

COMMENT:

No junctional component is seen and it is difficult to be certain if this is primary in this location. According to previous biopsy report, tumor was positive for S100, HMB45 and vimentin. Epithelial markers were negative. Microscopic sections reveal approximately 5% necrosis within the tumor with associated surface ulceration and foci of sparse tumor infiltrating lymphocytes.

Source: NCI Genomic Data Commons file 800f5734-b1f0-4d04-b857-03784008fa91 (TCGA-ER-A197.1286EE66-0342-45E4-A6E9-DCF8E1E94651.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).